Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A8RY, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A8RY-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

male with multiple left kidney lesions

Research Dx

Left kidney, laparoscopic nephrectomy:
Papillary renal cell carcinoma.

RD-0-3
Carcinoma, papillary renal cell
Site: Kidney NOS 8.26.13
064.9
JW 1/17/14

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: Laparoscopic nephrectomy

Specimen laterality: Left

Tumor site: Left kidney, central and superior

Tumor size: 4.5 by 4 x 4 cm (central) and 0.8 cm (superior)

Extent of disease: Limited to the kidney

Histologic type: Papillary renal cell carcinoma, type 1

Sarcomatoid features: Not identified

Tumor necrosis: Not identified

Histologic grade (Fuhrman Nuclear Grade): 2

Margins: Negative for carcinoma

Lymphovascular invasion: Not identified

Pathologic staging (pTNM):

Primary tumor: pT1b: Tumor more than 4 cm but less than 7 cm in greatest dimension, limited to the kidney

Regional lymph nodes: pNX: Unable to assess

Distant metastasis: pM: Not applicable

Pathologic findings in nonneoplastic kidney: None identified

Other tumors and/or tumor-like lesions: Papillary adenomata. Benign renal cyst.

AJCC Staging (7th edition) pT1b pNX pM: Not applicable

COMMENT

-

Research QC

Tumor:

99% tumor nuclei

0% necrosis

1% normal

Normal:

100% kidney

Research Specimen

-

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Cold ischemia start time

[page 2 of 2]
Formalin fixation start time:
Total cold ischemia time:
Formalin fixation stopped time:
Total formalin fixation time:

Specimen Weight

T1- 138mg, T2- mg, T3- mg, T4- mg
N1-191mg, N2- mg, N3- mg, N4- mg

Specimen Size

Plasma x 2
Serum x 2
Buffy coat x 1

Cryovials x 8
Normal x 4
Tumor x 4
Metastatic x 0

FFPE x 8
Normal x 4
Tumor x 4
Metastatic x 0

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file e6ac07e0-2013-4551-90e6-ee23eb7c9924 (TCGA-Y8-A8RY.67586735-59CF-41BF-8405-090C21EBCECF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).